Somatic mutation profile of tumor specimen MP2PRT-PANYZE-TMP1-A (aliquot MP2PRT-PANYZE-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANYZE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,479 days).
Specimen MP2PRT-PANYZE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15a87e99-ac63-45e7-94f7-427c97ef9f95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANYZE-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANYZE-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd62db98-e71b-43b5-b883-81394116c33b

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP2A2 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs767732105, COSV59960082; called by muse, mutect2, varscan2
- C21orf91 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 156/576 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53032847; called by muse, mutect2, varscan2
- CD8B2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs976215620; called by muse, mutect2, varscan2
- NPAS3 | c.586G>A p.D196N (on ENST00000356141 / NM_001164749.2; = p.D164N on NM_022123.3) | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1187772913, COSV58119987; called by muse, mutect2, varscan2
- PLEKHH1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 194/406 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs555885454, COSV61286381; called by muse, varscan2
- SPSB4 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 253/515 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1262932601; called by muse, mutect2, varscan2
- SUPT6H | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV58927143; called by muse, mutect2, varscan2
- ADAMTS16 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 166/402 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL18A1 | c.2008C>T p.L670F (on ENST00000359759 / NM_130444.3; = p.L435F on NM_030582.4) | Missense Mutation (SNP) | VAF 164/682 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, varscan2
- CREBBP | c.3185_3189del p.E1062Gfs*3 | Frame Shift Del (DEL) | VAF 148/385 reads (38%) | called by mutect2, pindel, varscan2
- FAM135B | c.1510dup p.I504Nfs*3 | Frame Shift Ins (INS) | VAF 103/298 reads (35%) | called by mutect2, pindel, varscan2
- FLG2 | c.6007G>T p.D2003Y | Missense Mutation (SNP) | VAF 145/279 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GATA6 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WASHC2A | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 137/337 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF219 | c.960C>A p.H320Q | Missense Mutation (SNP) | VAF 227/495 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C1QTNF4 | c.429G>A p.A143= | Silent (SNP) | VAF 208/432 reads (48%) | called by muse, mutect2, varscan2
- CLCA4 | c.2346T>C p.D782= | Silent (SNP) | VAF 56/132 reads (42%) | called by muse, varscan2
- LMTK3 | c.1665C>T p.N555= | Silent (SNP) | VAF 117/285 reads (41%) | called by muse, mutect2, varscan2
